Somatic mutation profile of tumor specimen 0DGIIM from CCDI case PBBTFP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Myxopapillary ependymoma; Tissue or organ of origin: Spinal cord; Age at diagnosis: 6.2 years (2,256 days).
Specimen 0DGIIM: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f46dc5ac-5c2e-4208-941f-3f40fee9e28c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DGIIN (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1a00433f-e980-4e06-8bb5-861753b0fc66

The open-access MAF lists 8 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COG4 | c.373C>T p.R125C | Missense Mutation (SNP) | VAF 232/630 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); catalogued as rs757774654, COSV60424253; called by muse, mutect2, varscan2
- NRK | c.4568G>A p.R1523H | Missense Mutation (SNP) | VAF 36/748 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.343); catalogued as rs746202742; called by muse, mutect2
- OTOP3 | c.440C>T p.S147F | Missense Mutation (SNP) | VAF 20/218 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs868785940, COSV60912533; called by muse, mutect2
- PSMC2 | c.99G>T p.L33F | Missense Mutation (SNP) | VAF 176/2209 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV53006863; called by muse, mutect2
- VWF | c.7549G>T p.V2517F | Missense Mutation (SNP) | VAF 34/308 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.481); catalogued as CM163329; called by muse, mutect2, varscan2
- PLA2R1 | c.918T>C p.S306= | Silent (SNP) | VAF 54/666 reads (8%) | called by muse, mutect2
- TTF1 | c.1242T>C p.S414= | Silent (SNP) | VAF 62/803 reads (8%) | catalogued as rs113184004; called by muse, mutect2
- CALCOCO2 | c.825+76T>A | Intron (SNP) | VAF 8/228 reads (4%) | called by muse, mutect2
